Gene-level copy-number profile of tumor specimen TCGA-E8-A437-01A from TCGA case TCGA-E8-A437, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 57.7 years (21,073 days).
Specimen TCGA-E8-A437-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THCA.f6f16819-a83b-414e-9d26-92aec8ab8dcc.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,573 have no estimate.
https://portal.gdc.cancer.gov/files/c2ce1b16-2bc5-4fde-adc7-cefe678841d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 34; copy number 2: 57,003; copy number 3: 12; copy number 5: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E8-A437-01A-12D-A23T-01): tumor purity 0.64, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:36,116,177–36,177,510, 1 gene, copy number 5: AC243829.2.

Autosomal genes at a single copy (total copy number 1): 34. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
